Somatic mutation profile of tumor specimen TCGA-A2-A1G4-01A (aliquot TCGA-A2-A1G4-01A-11D-A13L-09) from TCGA case TCGA-A2-A1G4, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 71.1 years (25,966 days).
Specimen TCGA-A2-A1G4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 71080bbb-5e47-4026-a207-0d6dfdf80a46.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A1G4-10A (Blood Derived Normal), aliquot TCGA-A2-A1G4-10A-01W-A14R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41077151-cedf-499c-957b-54c5b2c53694

The open-access MAF lists 31 somatic variants for this specimen: 22 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 17, Silent 9, Frame Shift Del 3, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RET | c.2332G>A p.V778I | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs75686697, CM022982, COSV60686303; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- AMOTL1 | c.749T>A p.L250Q | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV54414112; called by muse, mutect2, varscan2
- ATP6AP1 | c.256C>A p.P86T | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62340862; called by muse, mutect2, varscan2
- BEX4 | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as rs750282321, COSV65515817; called by muse, mutect2, varscan2
- ETV5 | c.819T>A p.H273Q | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV60499621; called by muse, mutect2, varscan2
- FAN1 | c.1750T>A p.F584I | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV62949608; called by muse, mutect2, varscan2
- FOXD4L3 | c.962A>T p.D321V | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as COSV61551133; called by mutect2, varscan2
- ITGA4 | c.421A>G p.I141V | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.018); catalogued as COSV51997598; called by muse, mutect2, varscan2
- KDM2A | c.1063C>T p.Q355* | Nonsense Mutation (SNP) | VAF 222/353 reads (63%) | catalogued as COSV67080886; called by muse, varscan2
- LRP1 | c.8327C>T p.P2776L | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as COSV54501296; called by muse, mutect2, varscan2
- MAP2K4 | c.752G>T p.S251I | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62254678, COSV62256920, COSV62260633; called by muse, mutect2, varscan2
- MYO6 | c.196A>T p.M66L | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as COSV64117064; called by muse, mutect2, varscan2
- PPARGC1A | c.1063T>A p.Y355N | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs749421285, COSV53524050, COSV53527071; called by muse, mutect2, varscan2
- PRDX5 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 115/161 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV50004498; called by muse, mutect2, varscan2
- RXRA | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs777558913, COSV62683418; called by muse, mutect2, varscan2
- SERPINA12 | c.602T>C p.V201A | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.101); catalogued as COSV57942029; called by muse, mutect2, varscan2
- SLC22A16 | c.995G>T p.G332V | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.335); catalogued as COSV57926925; called by muse, mutect2, varscan2
- YBX1 | c.797A>G p.N266S | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); catalogued as COSV58437057, COSV58438373; called by muse, mutect2, varscan2
- ATP11C | c.1528del p.R510Gfs*7 | Frame Shift Del (DEL) | VAF 42/128 reads (33%) | called by mutect2, varscan2
- COL6A5 | c.6225_6228del p.Y2075* (on ENST00000312481; = p.Y2071* on NM_153264.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 46/120 reads (38%) | called by mutect2, pindel, varscan2
- S100P | c.115_117del p.K39del | In Frame Del (DEL) | VAF 11/31 reads (35%) | called by mutect2, varscan2
- ZAN | c.4482_4486del p.W1495Qfs*11 | Frame Shift Del (DEL) | VAF 15/65 reads (23%) | called by mutect2, pindel, varscan2
- HNRNPUL2 | c.1773G>A p.E591= | Silent (SNP) | VAF 390/517 reads (75%) | catalogued as COSV57131074; called by muse, mutect2, varscan2
- IBTK | c.1614T>C p.I538= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV60390720; called by muse, mutect2, varscan2
- MCM9 | c.540C>T p.S180= | Silent (SNP) | VAF 43/114 reads (38%) | catalogued as COSV60163229; called by muse, mutect2, varscan2
- MYOF | c.5256G>A p.Q1752= | Silent (SNP) | VAF 55/116 reads (47%) | catalogued as rs772814311, COSV63699873; called by muse, mutect2, varscan2
- OR52B4 | c.225C>T p.L75= | Silent (SNP) | VAF 52/132 reads (39%) | catalogued as rs764484584, COSV101281583, COSV68768548; called by muse, mutect2, varscan2
- SH3BGRL | c.344G>A p.*115= | Silent (SNP) | VAF 54/126 reads (43%) | catalogued as COSV64619520; called by muse, mutect2, varscan2
- SLC9A4 | c.426C>T p.G142= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as rs575529823, COSV54828670, COSV54837751; called by muse, mutect2, varscan2
- SPATA21 | c.921C>G p.P307= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as COSV59185054; called by muse, mutect2, varscan2
- USP8 | c.942T>C p.N314= | Silent (SNP) | VAF 35/129 reads (27%) | catalogued as COSV56161950; called by muse, mutect2, varscan2
